Gene-level copy-number profile of tumor specimen TCGA-F4-6855-01A from TCGA case TCGA-F4-6855, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.9 years (25,890 days).
Specimen TCGA-F4-6855-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.81005054-35ca-4448-8dc8-1284fb1cf51f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F4-6855-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 357 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7740e6ee-ea00-4242-acd1-59b21be35b88

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10,188; copy number 1: 330; copy number 2: 38,885; copy number 3: 2,478; copy number 4: 8,384; copy number 11: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F4-6855-01A-11D-1923-01): tumor purity 0.65, ploidy 3, whole-genome doublings 1.

Caution: 9,667 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 9,667 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–72,282,539, 1,994 genes (within-gene range 0–1) (broad region; genes not listed).
- chr1:73,191,604–121,580,524, 862 genes (broad region; genes not listed).
- chr4:53,286–190,092,279, 2,654 genes (broad region; genes not listed).
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–1): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr15:19,878,555–101,933,350, 2,215 genes (broad region; genes not listed).
- chr16:6,380,476–6,874,005, 6 genes: AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.
- chr18:47,390–14,157,342, 332 genes (broad region; genes not listed).
- chr18:20,946,906–80,247,514, 863 genes (broad region; genes not listed).
- chr21:12,999,676–46,665,124, 735 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:208,266,059–208,270,667, 1 gene, copy number 11: AL606753.2.

Autosomal genes at a single copy (total copy number 1): 330. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
